Surgical pathology report (de-identified scan), TCGA case TCGA-CQ-7067, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University Health Network, Toronto, specimen TCGA-CQ-7067-01A (Primary Tumor).

[page 1 of 4]
Patient Name	MRN	Visit Number

Event Date and Time	Procedure Ordered	Status	Ordered By	Specimen #
	Surgical Pathology Report	complete		
Collection Date:				
Accession Date:				
Result Date:				
Copath:				

Surgical Pathology Consultation Report

SPECIMEN(S) RECEIVED

1. Skin: scar neck, previous tracheostomy
2. Neck: Lt neck level 1
3. Neck: Lt neck level 2A
4. Neck: Lt neck level 3
5. Neck: Lt hemi-glossectomy(long stitch-anterior / short=medial)
6. Neck: deep margin
7. Neck: medial resection margin
8. Surgical Waste

DIAGNOSIS

1. Scar neck, previous tracheostomy.

Skin with scar.

2. Left neck level I.

Three lymph nodes negative for tumor (0/3).

Submandibular gland with no pathologic changes.

3. Left neck level IIA.

One lymph node negative for tumor (0/1).

4. Left neck level III.

Eleven lymph nodes negative for tumor (0/11).

5. Oral cavity; tongue; left hemiglossectomy.

Squamous cell carcinoma, poorly differentiated.

1. Maximum tumor diameter 2.0 cm.

2. Tumor thickness 0.6 cm.

3. No lymphovascular invasion.

4. Focal perineural invasion is present.

5. The lateral and medial margins are close (0.3) to tumor. The remaining margins are negative for tumor.

6. Deep margin.

Negative for tumor.

[page 2 of 4]
7. Medial resection margin.

Squamous mucosa negative for tumor.

8. Surgical waste.

Adipose tissue with no pathologic changes. (Gross examination only)

SYNOPTIC DATA

Specimen Type: Resection: Left hemiglossectomy.

Tumor Site: Tongue

Histologic Type: Squamous cell carcinoma, conventional

Tumor Size: Greatest dimension: 2.0 cm

Tumor thickness: 0.6 cm

Histologic Grade: G3: Poorly differentiated

Venous/Lymphatic (Large/Small Vessel) Invasion (V/L): Absent

Perineural Invasion: Present

Margins: Margins uninvolved by tumor

Margins uninvolved by tumor - Distance of

tumor from closest margin: 0.3 cm

Margins: Lateral and medial margins.

Pathologic Staging (pTNM): pT1: Tumor of lip or oral cavity 2 cm or less in greatest dimension

pN0: No regional lymph node metastasis for aerodigestive sites

Number of regional lymph nodes examined: 15

Number of regional lymph nodes involved: 0

pMX: Distant metastasis cannot be assessed

*Pathologic Staging is based on AJCC/UICC TNM, [redacted] Edition

ELECTRONICALLY VERIFIED BY [redacted]

CLINICAL HISTORY

tongue ca

GROSS DESCRIPTION

1. The specimen is labeled with the patient's name and as "scar neck previous tracheostomy". It consists of an ellipse of unremarkable skin measuring 3.7 x 1 x 0.5 cm.

1A representative sections

2. The specimen is labeled with the patient's name and "left neck level 1". It consists of fibroadipose tissue measuring 7 x 4.5 x 2.2 cm. The

[page 3 of 4]
submandibular gland measures 3.5 x 2.5 x 1.8 cm and is unremarkable. Multiple lymph nodes ranging from 0.3 to 1.8 cm are identified.

2A submandibular gland

2B one lymph node

2C one lymph node

3. The specimen is labeled with the patient's name and "left neck labeled 2A.". It consists of fibroadipose tissue measuring 4 x 2.8 x 1 cm. One lymph node measuring 0.2cm is identified.

3A one lymph node

4. The specimen is labeled with the patient's name and "left neck level 3". It consists of fibroadipose tissue measuring 5.5 x 4.4 x 1.3 cm. Multiple lymph nodes ranging from 0.3 x 0.2 x 0.2 to 1 x 1 x 0.6 cm are identified.

4A-4B multiple lymph nodes

4C one lymph node

5. The specimen is labeled the patient's name and as "left hemiglossectomy long stitch anterior short medial". It consists of an oriented portion of left tongue measuring 1.6 SI x 3.5 ML x 4.3 AP cm. There is a partially ulcerated tumor involving the tongue. The tumor measures 0.6 SI x 2 ML x 2 AP cm. The tumor is homogeneous and is located at 0.3 cm from the lateral margin, 0.3 cm from the medial margin, 0.5 cm from the deep margin, 1.1 cm from the anterior margin, and 0.4 from the posterior margin. Representative sections are submitted.

5A lateral margin

5B medial margin

5C deep margin

5D anterior margin

5E posterior margin

5F-5G tumor

6. The specimen is labeled with the patient's name and as "deep margin". It consists of a fragment of tissue measuring 1.6 x 0.6 x 0.3 cm. The specimen is submitted in toto for frozen section.

6A frozen section control

7. The specimen is labeled with the patient's name and as "medial resection margin". It consists of a fragment of tissue measuring 1.7 x 1.5 x 0.6 cm. The specimen is submitted in toto for frozen section.

7A frozen section control

8. The specimen is labeled with the patient's name and as "surgical waste". It consists of one piece of unremarkable adipose tissue measuring 14 x 4 x 1.4 cm. No sections are submitted.

[page 4 of 4]
QUICK SECTION

- 6. Margin negative for malignancy
- 7. Margin negative for malignancy

Source: NCI Genomic Data Commons file 03266c8a-aeea-46b6-8412-99df444e53f1 (TCGA-CQ-7067.0821BD7B-9F5A-4E90-8082-2900B444DFF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).